Gene-level copy-number profile of tumor specimen TCGA-XF-A8HC-01A from TCGA case TCGA-XF-A8HC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 79.4 years (28,996 days).
Specimen TCGA-XF-A8HC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.ddc9238e-d894-43d9-a73f-30fee2791303.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A8HC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/07e3f1bc-e9e6-4954-8906-8a8c74f4bbfc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,635; copy number 2: 15,676; copy number 3: 27,883; copy number 4: 9,804; copy number 5: 3,231; copy number 6: 387; copy number 7: 630; copy number 8: 182; copy number 10: 115; copy number 12: 254; copy number 14: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A8HC-01A-11D-A363-01): tumor purity 0.96, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,187 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,937,812–161,422,424, 588 genes, copy number 7–12 (within-gene range 5–12) (broad region; genes not listed).
- chr1:161,406,068–161,411,802, 2 genes, copy number 12: AL592295.1, AL592295.2.
- chr3:194,202,392–198,222,513, 151 genes, copy number 7 (broad region; genes not listed).
- chr4:132,836,772–152,116,497, 262 genes, copy number 8–14 (broad region; genes not listed).
- chr5:8,333,481–10,082,772, 41 genes, copy number 8 (within-gene range 4–8): LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4.
- chr16:27,998,295–30,123,506, 143 genes, copy number 12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,289. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
